Somatic mutation profile of cancer-model specimen HCM-BROD-0611-C71-85R (Adherent Cell Line, passage 5; aliquot HCM-BROD-0611-C71-85R-01D-A83U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0611-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.5 years (20,992 days).
Specimen HCM-BROD-0611-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbb708f5-6c95-4194-bc59-f2b9c876e094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0611-C71-10B (Blood Derived Normal), aliquot HCM-BROD-0611-C71-10B-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d5756da-4879-4e70-a6a5-bb8b2271cda9

The open-access MAF lists 82 somatic variants for this specimen: 60 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 45, Silent 22, Frame Shift Del 9, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 172/357 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908716, CM880002; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2060T>C p.V687A | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV60631759; called by muse, mutect2, varscan2
- ADGRV1 | c.9623G>T p.R3208I | Missense Mutation (SNP) | VAF 97/113 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV67983323; called by muse, mutect2, varscan2
- ALAS2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 189/437 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs201086991, COSV100238716; called by muse, mutect2, varscan2
- CACNA1G | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 177/351 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.085); catalogued as rs1474133086, COSV100661369; called by muse, mutect2, varscan2
- DPPA4 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 171/404 reads (42%) | catalogued as rs779870487, COSV59509201, COSV59509876; called by muse, mutect2, varscan2
- EXTL1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 251/509 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs375069374; called by muse, mutect2, varscan2
- FMNL1 | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.266); catalogued as rs748632258; called by muse, mutect2, varscan2
- FTSJ3 | c.2193del p.W731Cfs*24 | Frame Shift Del (DEL) | VAF 195/556 reads (35%) | catalogued as COSV63790968; called by mutect2, pindel, varscan2
- IPO4 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs768075624, COSV99938126; called by muse, mutect2, varscan2
- KANK2 | c.1529C>T p.S510L (on ENST00000586659 / NM_001379562.1; = p.S518L on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs775590836; called by muse, mutect2
- KRTAP10-6 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 35/750 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.426); catalogued as rs1555926531; called by muse, mutect2
- MAPKAP1 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 14/464 reads (3%) | catalogued as COSV56373152; called by muse, mutect2
- NPTX2 | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 176/505 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770355969, COSV99674762; called by muse, mutect2, varscan2
- OR4D9 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 219/443 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs200344506, COSV61434610; called by muse, mutect2, varscan2
- PHRF1 | c.2513C>A p.S838Y (on ENST00000264555 / NM_001286581.2; = p.S837Y on NM_020901.4) | Missense Mutation (SNP) | VAF 334/819 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52764305; called by muse, mutect2, varscan2
- PRKDC | c.3187C>A p.L1063I | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.16); catalogued as COSV100043348; called by muse, mutect2, varscan2
- PROKR1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 245/493 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs143892402, COSV58136477; called by muse, mutect2
- PRR35 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 348/766 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs995990707, COSV53462570; called by muse, mutect2
- RASGRF1 | c.327del p.R110Gfs*30 | Frame Shift Del (DEL) | VAF 124/447 reads (28%) | catalogued as COSV69183916; called by mutect2, pindel, varscan2
- RNASEH2B | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 264/607 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs531904107; called by muse, mutect2, varscan2
- RPP38 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs201405215; called by muse, mutect2, varscan2
- STAG3 | c.3052dup p.R1018Pfs*62 | Frame Shift Ins (INS) | VAF 212/431 reads (49%) | catalogued as rs771420693; called by mutect2, pindel, varscan2
- TMPO | c.1817C>A p.S606* | Nonsense Mutation (SNP) | VAF 197/235 reads (84%) | catalogued as COSV54123855, COSV99702261; called by muse, mutect2, varscan2
- TNS4 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 313/643 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs779522697, COSV99563661; called by muse, mutect2
- TRIP12 | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52260207; called by muse, mutect2, varscan2
- VAX1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1239668375; called by muse, mutect2, varscan2
- XPNPEP3 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV63210235; called by muse, mutect2, varscan2
- XPO6 | c.1838T>C p.L613S | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58964676; called by muse, varscan2
- ARHGAP18 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C6orf132 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 393/857 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CARD6 | c.1712dup p.L571Ffs*7 | Frame Shift Ins (INS) | VAF 129/321 reads (40%) | called by mutect2, pindel, varscan2
- DENND2B | c.3340A>G p.T1114A | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- EPHA1 | c.1617G>A p.V539= | Splice Region (SNP) | VAF 137/530 reads (26%) | called by muse, mutect2, varscan2
- FES | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 225/584 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GPR34 | c.345_351del p.N116Tfs*5 | Frame Shift Del (DEL) | VAF 208/429 reads (48%) | called by mutect2, pindel, varscan2
- GPX3 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 133/329 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- GXYLT1 | c.605T>G p.F202C | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNA5 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 383/558 reads (69%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF22 | c.1086_1096del p.A363Gfs*10 | Frame Shift Del (DEL) | VAF 118/400 reads (30%) | called by mutect2, pindel, varscan2
- KIF4A | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, varscan2
- LHX1 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 411/801 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1B | c.9566A>G p.Y3189C | Missense Mutation (SNP) | VAF 101/209 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MOSMO | c.207_208del p.F71Yfs*54 | Frame Shift Del (DEL) | VAF 135/543 reads (25%) | called by mutect2, pindel, varscan2
- MYOM2 | c.4066A>C p.I1356L | Missense Mutation (SNP) | VAF 257/558 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PDE3B | c.517T>C p.S173P | Missense Mutation (SNP) | VAF 452/901 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHEX | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 183/473 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PHF12 | c.2498G>A p.C833Y | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPM1E | c.1014A>C p.R338S | Missense Mutation (SNP) | VAF 170/377 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PRPS1 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 105/319 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PYGL | c.438T>G p.D146E | Missense Mutation (SNP) | VAF 99/125 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RERE | c.3734_3758del p.Y1245Ffs*4 | Frame Shift Del (DEL) | VAF 199/302 reads (66%) | called by pindel, varscan2
- SENP5 | c.641del p.P214Qfs*12 | Frame Shift Del (DEL) | VAF 137/582 reads (24%) | called by mutect2, pindel, varscan2
- SERPINB3 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SLC35F3 | c.566C>A p.A189D (on ENST00000366617 / NM_001300845.1; = p.A258D on NM_173508.4) | Missense Mutation (SNP) | VAF 151/345 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- SORT1 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 161/343 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- TTF2 | c.1973A>G p.N658S | Missense Mutation (SNP) | VAF 125/400 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- TUBB4A | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 243/669 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP47 | c.3494_3503del p.E1165Vfs*2 (on ENST00000399455 / NM_001372095.1; = p.E1077Vfs*2 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 74/236 reads (31%) | called by mutect2, pindel, varscan2
- XPO6 | c.1823_1829del p.A608Dfs*4 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by pindel, varscan2
- ANO3 | c.2544C>T p.G848= | Silent (SNP) | VAF 101/264 reads (38%) | catalogued as rs753582126; called by muse, mutect2, varscan2
- CACNA1I | c.915G>A p.A305= | Silent (SNP) | VAF 335/725 reads (46%) | catalogued as rs59107946; called by muse, mutect2, varscan2
- CBX8 | c.666C>A p.L222= | Silent (SNP) | VAF 262/542 reads (48%) | called by muse, varscan2
- CDC16 | c.567C>A p.P189= | Silent (SNP) | VAF 102/236 reads (43%) | catalogued as COSV52962554; called by muse, mutect2, varscan2
- CHADL | c.240C>T p.A80= | Silent (SNP) | VAF 264/591 reads (45%) | called by muse, mutect2, varscan2
- CLK1 | c.1146C>T p.H382= | Silent (SNP) | VAF 101/215 reads (47%) | catalogued as rs138594554; called by muse, mutect2, varscan2
- CREB3L4 | c.438A>G p.A146= | Silent (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- ELAVL3 | c.708T>C p.R236= | Silent (SNP) | VAF 143/376 reads (38%) | called by muse, mutect2, varscan2
- HSPA1A | c.1746C>T p.D582= | Silent (SNP) | VAF 360/565 reads (64%) | catalogued as rs771552351; called by muse, mutect2, varscan2
- ISLR2 | c.837C>T p.G279= | Silent (SNP) | VAF 201/480 reads (42%) | catalogued as rs775614352; called by muse, mutect2, varscan2
- MLF1 | c.30G>A p.E10= | Silent (SNP) | VAF 470/750 reads (63%) | called by muse, mutect2, varscan2
- MUC4 | c.489C>T p.T163= | Silent (SNP) | VAF 588/951 reads (62%) | called by muse, mutect2, varscan2
- NPHS2 | c.129C>A p.P43= | Silent (SNP) | VAF 68/1248 reads (5%) | called by muse, mutect2
- NTSR1 | c.900C>T p.H300= | Silent (SNP) | VAF 226/428 reads (53%) | catalogued as rs772417399, COSV100980643; called by muse, mutect2, varscan2
- PPFIBP1 | c.1555C>A p.R519= (on ENST00000318304 / NM_177444.3; = p.R502= on NM_003622.4) | Silent (SNP) | VAF 188/404 reads (47%) | catalogued as COSV57291371; called by muse, varscan2
- RERE | c.3765T>A p.T1255= | Silent (SNP) | VAF 227/292 reads (78%) | catalogued as rs987730776; called by muse, varscan2
- SPTA1 | c.327T>G p.S109= | Silent (SNP) | VAF 107/289 reads (37%) | called by muse, mutect2, varscan2
- TBC1D5 | c.1161C>G p.T387= | Silent (SNP) | VAF 87/261 reads (33%) | called by muse, mutect2, varscan2
- TMC4 | c.819G>A p.S273= (on ENST00000617472 / NM_001145303.3; = p.S267= on NM_144686.4) | Silent (SNP) | VAF 257/494 reads (52%) | called by muse, mutect2, varscan2
- WDR19 | c.696C>G p.G232= | Silent (SNP) | VAF 89/234 reads (38%) | called by muse, mutect2, varscan2
- XIRP2 | c.4293A>G p.R1431= (on ENST00000628543; = p.R1606= on NM_152381.6) | Silent (SNP) | VAF 15/358 reads (4%) | called by muse, mutect2
- ZNF493 | c.1263A>G p.E421= | Silent (SNP) | VAF 158/411 reads (38%) | called by muse, mutect2, varscan2
